Gene-level copy-number profile of tumor specimen ALCH-B28E-TTP1-A from ALCHEMIST case ALCH-B28E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,697 days).
Specimen ALCH-B28E-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 64f81791-bf18-430f-9d9e-a699e4a9d868.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B28E-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/072593e1-ab9b-4be2-bd42-a73b4cfec5df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 759; copy number 2: 57,188; copy number 3: 182; copy number 4: 240; copy number 11: 3; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,099,092–130,111,472, 1 gene (within-gene range 0–2): FAM86HP.
- chr7:44,512,535–44,541,330, 1 gene: NPC1L1.
- chr9:136,647,872–136,687,457, 4 genes (within-gene range 0–2): AL590226.1, EGFL7, MIR126, AGPAT2.
- chr11:119,121,580–119,184,016, 3 genes: HINFP, ABCG4, NLRX1.
- chr17:17,507,351–17,508,308, 1 gene (within-gene range 0–2): AC020558.2.
- chr17:50,110,040–50,130,160, 1 gene (within-gene range 0–2): SAMD14.
- chr19:45,071,500–45,092,635, 3 genes (within-gene range 0–2): ZNF296, GEMIN7-AS1, GEMIN7.
- chr19:45,091,396–45,160,815, 4 genes (within-gene range 0–2): PPP1R37, EIF5AP3, AC005757.1, NKPD1.
- chr20:34,688,688–34,688,978, 1 gene (within-gene range 0–2): AL118520.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:27,657–37,269, 3 genes, copy number 11 (within-gene range 4–11): MIR1302-9HG, MIR1302-9, FAM138C.
- chr21:43,461,960–43,479,534, 2 genes, copy number 12: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 759. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
